Somatic mutation profile of tumor specimen 0DENCS from CCDI case PBBNSR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Optic nerve; Age at diagnosis: 17.4 years (6,344 days).
Specimen 0DENCS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fd2507d-a459-470a-a492-d4b4b0139415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DENBU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b192de-0624-44a2-af59-206874b0a52b

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GMIP | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 55/562 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756939592; called by muse, mutect2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 184/473 reads (39%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- SLC38A5 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 78/976 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1466808513, COSV58333379; called by muse, mutect2
- TKTL2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 31/731 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139831361; called by muse, mutect2
- TTN | c.71879C>T p.T23960M (on ENST00000591111; = p.T16536M on NM_003319.4) | Missense Mutation (SNP) | VAF 63/452 reads (14%) | PolyPhen probably damaging (0.986); catalogued as rs374913031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF524 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 69/486 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190140991; called by muse, mutect2, varscan2
- C15orf48 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CARMIL2 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 306/782 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- E2F2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 24/684 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NF1 | c.5030_5060del p.V1677Gfs*11 (on ENST00000358273 / NM_001042492.3; = p.V1656Gfs*11 on NM_000267.3) | Frame Shift Del (DEL) | VAF 347/520 reads (67%) | called by mutect2, pindel, varscan2
- POLR3B | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCD | c.1800C>A p.H600Q | Missense Mutation (SNP) | VAF 105/559 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PUDP | c.131A>T p.D44V | Missense Mutation (SNP) | VAF 102/629 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TGDS | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CFAP46 | c.1113C>T p.A371= | Silent (SNP) | VAF 69/544 reads (13%) | catalogued as rs571453045; called by muse, mutect2, varscan2
- CTTNBP2 | c.4797A>G p.K1599= | Silent (SNP) | VAF 97/804 reads (12%) | called by muse, mutect2, varscan2
- TECTA | c.123A>G p.V41= | Silent (SNP) | VAF 22/798 reads (3%) | called by muse, mutect2
- CCDC154 | c.8-61C>T | Intron (SNP) | VAF 19/189 reads (10%) | catalogued as rs567924818; called by muse, mutect2, varscan2
- OSBPL7 | c.1023+29G>A | Intron (SNP) | VAF 43/324 reads (13%) | catalogued as rs781684898; called by muse, mutect2, varscan2
- SLC35A2 | chrX:48911707 G>A | 5'Flank (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
